CCDI case PBBUNK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/bdc1f354-a142-46c1-a0e4-f4900ed34ba7

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 6.5 years (2,372 days).

Biospecimens (2 samples)
- Sample 0DHHIZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHHL8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
